Gene-level copy-number profile of tumor specimen TCGA-MP-A4T6-01A from TCGA case TCGA-MP-A4T6, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 76.6 years (27,993 days).
Specimen TCGA-MP-A4T6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.5248c745-c320-426c-8c2f-e0f0df34b076.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MP-A4T6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/b22a5e18-7ff3-4c08-b808-5efeee9c2f68

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 1,218; copy number 2: 18,324; copy number 3: 9,932; copy number 4: 12,725; copy number 5: 8,903; copy number 6: 5,494; copy number 7: 2,826; copy number 8: 205; copy number 10: 73; copy number 12: 46; copy number 14: 11; copy number 16: 40.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,214,672, 18 genes (within-gene range 0–1): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17,456 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–45,306,209, 1,469 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 7 (broad region; genes not listed).
- chr3:11,745–846,561, 11 genes, copy number 5 (within-gene range 2–5): LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32.
- chr3:87,226,189–119,629,811, 379 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr5:58,198–42,191,523, 649 genes, copy number 5 (broad region; genes not listed).
- chr6:70,412,941–76,447,089, 103 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr7:70,972–101,161,596, 1,876 genes, copy number 5–6 (broad region; genes not listed).
- chr11:167,784–60,687,267, 1,466 genes, copy number 5 (broad region; genes not listed).
- chr11:78,652,829–135,075,908, 1,088 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–21,419,594, 598 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr12:47,593,208–79,452,008, 910 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr14:18,333,726–106,875,071, 2,285 genes, copy number 5–16 (broad region; genes not listed).
- chr16:11,555–90,222,851, 2,560 genes, copy number 5–6 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,218. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
